ALCHEMIST case ALCH-B2AS — Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial (ALCHEMIST-ALCH)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026).
https://portal.gdc.cancer.gov/cases/118ea681-3db8-48df-a84b-880650340e61

Demographics
Sex at birth: male.

Diagnoses (1)
1. Squamous cell carcinoma, NOS: Age at diagnosis: 53.8 years (19,667 days).

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample ALCH-B2AS-NB1-A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Whole Blood; Preservation method: Fresh.
- Sample ALCH-B2AS-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide ALCH-B2AS-TTP1-A-1-0-S1: Section location: Top; Percent tumor cells: 32; Percent tumor nuclei: 40; Percent normal cells: 33; Percent necrosis: 1; Percent stromal cells: 34; Percent lymphocyte infiltration: 38; Percent monocyte infiltration: 16; Percent neutrophil infiltration: 1.
